Somatic mutation profile of tumor specimen TCGA-CV-7433-01A (aliquot TCGA-CV-7433-01A-11D-2129-08) from TCGA case TCGA-CV-7433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.3 years (18,004 days).
Specimen TCGA-CV-7433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de3259ad-c9e7-482f-9889-3c62bf127178.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7433-10A (Blood Derived Normal), aliquot TCGA-CV-7433-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404b985e-94c5-4056-a826-5cea9f1e5929

The open-access MAF lists 119 somatic variants for this specimen: 84 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 34, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LTBP3 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs1554973844, COSV57244376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53037970, COSV53045435; called by muse, mutect2, varscan2
- AC068580.4 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52588247; called by muse, mutect2
- AC090517.4 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV50997760, COSV99974311; called by muse, mutect2, varscan2
- ACD | c.1478G>T p.R493M (on ENST00000620338; = p.R404M on NM_022914.3) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99537575; called by muse, mutect2, varscan2
- ADCY8 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99651605; called by muse, mutect2, varscan2
- ADGRF2 | c.352C>T p.Q118* (on ENST00000296862 / NM_001368115.2; = p.Q50* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as rs771787941, COSV99731003; called by muse, mutect2, varscan2
- ADRA1B | c.74T>G p.F25C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV100140167; called by muse, mutect2
- AFM | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.339); catalogued as COSV99888685; called by muse, mutect2, varscan2
- AP1G1 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV100250270; called by muse, mutect2, varscan2
- ASXL1 | c.2663A>G p.K888R | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); catalogued as COSV100038580; called by muse, mutect2, varscan2
- ATAD5 | c.4522T>C p.Y1508H | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100429828; called by muse, mutect2, varscan2
- BTC | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1560707045, COSV101201504, COSV67547616; called by muse, mutect2, varscan2
- CARD6 | c.2785C>A p.L929I | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99620602; called by muse, mutect2, varscan2
- CASKIN1 | c.960G>T p.W320C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623958; called by muse, mutect2, varscan2
- CCDC8 | c.1523G>C p.R508T | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100281981; called by muse, mutect2, varscan2
- CCDC8 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.161); catalogued as rs765051486, COSV100281984; called by muse, mutect2
- CCNE1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 8/157 reads (5%) | catalogued as COSV99388274; called by muse, mutect2
- CECR2 | c.2382G>A p.W794* (on ENST00000342247 / NM_001290047.2; = p.W611* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52845317, COSV99377571; called by muse, mutect2, varscan2
- CXCL14 | c.288C>G p.I96M (on ENST00000337225; = p.I84M on NM_004887.5) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100463562; called by muse, mutect2
- DCK | c.737A>T p.Y246F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs745977177, COSV99709157; called by muse, mutect2, varscan2
- DDX21 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV100826505; called by muse, mutect2, varscan2
- DEF8 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.605); catalogued as COSV99240388; called by muse, mutect2
- DNAH11 | c.5557T>C p.F1853L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100178493; called by muse, mutect2
- DNAH11 | c.6637C>G p.L2213V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100178496; called by muse, mutect2
- DSP | c.6024C>G p.I2008M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV101131227; called by muse, mutect2, varscan2
- FKBP14 | c.141G>C p.L47F | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99321593; called by muse, mutect2, varscan2
- FOCAD | c.2537A>G p.Y846C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100620255; called by muse, mutect2, varscan2
- FRMD5 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101296379; called by muse, mutect2, varscan2
- GGCT | c.334G>C p.V112L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50040834; called by muse, mutect2
- HIP1 | c.2952+1G>A p.X984_splice | Splice Site (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100417294, COSV61187362; called by muse, mutect2, varscan2
- HMGXB4 | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99330001; called by muse, mutect2, varscan2
- HS3ST5 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV57141654; called by muse, mutect2
- IL12RB2 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99254930; called by muse, mutect2
- MIP | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as COSV99234172; called by muse, mutect2
- MROH7 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100273295; called by muse, mutect2, varscan2
- MTCL1 | c.1334A>T p.K445M (on ENST00000306329 / NM_001378206.1; = p.K85M on NM_015210.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100094104; called by muse, mutect2, varscan2
- MXRA5 | c.3989T>C p.V1330A | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99476429; called by muse, mutect2, varscan2
- NLRP3 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs199856287, CM1413286, COSV60219661, COSV60221397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPY1R | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99648641; called by muse, mutect2, varscan2
- NR3C1 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99196199; called by muse, mutect2
- NTSR1 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100980636; called by muse, mutect2
- OR10G4 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100304773; called by muse, mutect2, varscan2
- OR1B1 | c.37dup p.V13Gfs*11 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | catalogued as COSV59171056; called by mutect2, pindel
- OR2T3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100613009; called by muse, mutect2
- OR4K13 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs768232948, COSV59860786; called by muse, mutect2, varscan2
- OR4K2 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100064325, COSV53848263; called by muse, mutect2, varscan2
- PCDHB7 | c.145G>C p.A49P | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99176674; called by muse, mutect2, varscan2
- PCDHB7 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.049); catalogued as COSV99176677; called by muse, mutect2, varscan2
- PCDHGA7 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1390926308, COSV53984296; called by muse, mutect2, varscan2
- PDZRN4 | c.1995G>C p.E665D (on ENST00000402685 / NM_001164595.2; = p.E407D on NM_013377.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100114146; called by muse, mutect2, varscan2
- PKP4 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101080663; called by muse, mutect2, varscan2
- PLSCR4 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100724168; called by muse, mutect2, varscan2
- POR | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV100115544; called by muse, mutect2, varscan2
- PPP2R5D | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758921014, COSV55150259; called by muse, mutect2
- PRSS22 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs1414561910, COSV50720891; called by muse, mutect2, varscan2
- PWP1 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV101338801; called by muse, mutect2, varscan2
- RET | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100393141; called by muse, mutect2, varscan2
- RICTOR | c.2462G>A p.R821K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as COSV99704695; called by muse, mutect2, varscan2
- ROCK2 | c.2810C>G p.S937C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV59957250; called by muse, mutect2, varscan2
- RSPH4A | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 23/222 reads (10%) | catalogued as COSV57635672; called by muse, mutect2
- RTN4 | c.2602A>G p.I868V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs757479536, COSV100462957; called by muse, mutect2, varscan2
- SERPINA4 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs957301897, COSV100097090, COSV54069133; called by muse, mutect2
- SI | c.4496G>A p.G1499E | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376892049; called by muse, mutect2
- SLC22A14 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99828184; called by muse, mutect2, varscan2
- SLC35B2 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs150122797, COSV99241033; called by muse, mutect2
- SLC6A3 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as rs372788698, COSV54362199; called by muse, mutect2
- SOX12 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100705233; called by mutect2, varscan2
- STAM2 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs778505784, COSV99812958; called by muse, mutect2, varscan2
- TAS1R1 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039429; called by muse, mutect2, varscan2
- TBK1 | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100538107; called by muse, mutect2, varscan2
- THOC5 | c.1603T>C p.F535L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs757853867, COSV100803528; called by muse, mutect2, varscan2
- TLN2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs554667095, COSV60887358; called by muse, mutect2
- TTC33 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.444); catalogued as COSV100531858; called by muse, mutect2
- UBA52 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs778056854, COSV99723649; called by muse, mutect2, varscan2
- UNC79 | c.1396G>A p.E466K (on ENST00000393151 / NM_001346218.2; = p.E289K on NM_020818.5) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV99827006; called by muse, mutect2
- USP9X | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100198874; called by muse, mutect2, varscan2
- ZBTB22 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56469807, COSV99801873; called by muse, mutect2
- ZSWIM4 | c.2347T>G p.S783A | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99584699; called by muse, mutect2
- IL25 | c.16_23del p.R6* | Frame Shift Del (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- KIFC3 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MSH6 | c.1581_1594del p.E528* | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel
- PLG | c.919del p.H307Ifs*64 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- TADA2A | c.493A>G p.M165V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- CFHR1 | c.394C>A p.R132= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100258746; called by muse, mutect2, varscan2
- CNOT6L | c.99A>G p.K33= (on ENST00000504123 / NM_001286790.2; = p.K28= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as rs200743940, COSV99361610; called by muse, mutect2, varscan2
- DSP | c.5025C>T p.V1675= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV101131226, COSV65794106; called by muse, mutect2
- EMID1 | c.534G>T p.P178= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs376315194, COSV61828856; called by muse, varscan2
- F11R | c.42C>G p.L14= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs369249236; called by muse, mutect2, varscan2
- GABRA4 | c.423C>G p.V141= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99973843; called by muse, mutect2
- HEPACAM | c.306T>C p.F102= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV100005606; called by muse, mutect2, varscan2
- ID2 | c.330C>T p.I110= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99301069; called by muse, mutect2
- JAG1 | c.2712C>T p.L904= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99652686; called by muse, mutect2, varscan2
- KCNJ4 | c.117G>A p.S39= | Silent (SNP) | VAF 57/353 reads (16%) | catalogued as rs371561137; called by muse, mutect2, varscan2
- KCTD13 | c.135G>A p.L45= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100442083; called by muse, mutect2, varscan2
- LRP12 | c.2256G>A p.Q752= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs1167506784, COSV99407502; called by muse, mutect2, varscan2
- MFSD11 | c.33C>T p.I11= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100333730; called by muse, mutect2, varscan2
- MTARC1 | c.945G>C p.G315= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100856273; called by muse, mutect2
- NFATC2IP | c.807C>T p.I269= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV57911377; called by muse, mutect2
- NOTCH4 | c.2943A>T p.G981= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100900590; called by muse, mutect2, varscan2
- OLR1 | c.294A>T p.S98= | Silent (SNP) | VAF 11/188 reads (6%) | catalogued as COSV100376349; called by muse, mutect2
- OR4X2 | c.201C>T p.S67= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs773448537, COSV56582035, COSV56585087; called by muse, mutect2, varscan2
- PDCD4 | c.249C>T p.D83= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs538533354, COSV54521987; called by muse, mutect2, varscan2
- PEX5 | c.42C>T p.A14= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99870828; called by muse, mutect2, varscan2
- PFKFB4 | c.1263G>C p.L421= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99219523; called by muse, mutect2, varscan2
- PTPN21 | c.3066C>A p.T1022= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100161755; called by muse, mutect2, varscan2
- RGS7BP | c.436C>T p.L146= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs1346108129, COSV61834498; called by muse, mutect2
- SATB2 | c.480A>T p.S160= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99610949; called by muse, mutect2
- SLC2A11 | c.426G>A p.Q142= (on ENST00000345044 / NM_001024938.4; = p.Q149= on NM_030807.5) | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99741328; called by muse, mutect2, varscan2
- SPEN | c.4368A>G p.S1456= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs1436131726, COSV101005114; called by muse, mutect2, varscan2
- SPON1 | c.1128C>A p.I376= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs895112796, COSV100115607; called by muse, mutect2, varscan2
- SSH2 | c.579G>A p.A193= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs753403781, COSV99281788; called by muse, mutect2, varscan2
- SSR2 | c.60A>T p.G20= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99828554; called by muse, mutect2, varscan2
- STON2 | c.1473C>A p.I491= (on ENST00000649389 / NM_001366849.2; = p.I434= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as COSV99964616; called by muse, mutect2
- TCAF2 | c.384C>T p.I128= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100633576; called by muse, mutect2
- TRPV4 | c.1422C>T p.N474= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs140533102; ClinVar: likely benign; called by muse, mutect2
- VPS13B | c.3696C>A p.I1232= | Silent (SNP) | VAF 42/373 reads (11%) | catalogued as COSV100661575, COSV62138561; called by muse, mutect2, varscan2
- VPS13B | c.7992C>T p.S2664= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as COSV100661576; called by muse, mutect2, varscan2
- ZNF658B | n.2443T>G | RNA (SNP) | VAF 16/60 reads (27%) | called by mutect2, varscan2
